Somatic mutation profile of tumor specimen BA3328D (aliquot aq-BA3328D) from BEATAML1.0 case 2741, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.9 years (23,345 days).
Specimen BA3328D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f521740b-646a-4ffd-bf1f-ef38618d7665.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3244D (Solid Tissue Normal), aliquot aq-BA3244D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afc5f4f9-20e0-4e27-99d9-fea4492591b7

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Del 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOXE3 | c.616A>C p.M206L | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCNX3 | c.2283del p.Y761* | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | called by mutect2, varscan2
